Somatic mutation profile of tumor specimen 4b263734-430f-41dc-a296-8691f0 (aliquot 4b263734-430f-41dc-a296-8691f0_D6) from CPTAC case 06CO002, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB.
Specimen 4b263734-430f-41dc-a296-8691f0: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce1eb9ac-e12e-43d6-8884-6e498f9089e6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0cf1768a-8df5-4648-ba22-00f0fb (Blood Derived Normal), aliquot 0cf1768a-8df5-4648-ba22-00f0fb_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce3eeeba-0971-44ed-b647-5716568d6945

The open-access MAF lists 128 somatic variants for this specimen: 75 protein-altering or splice-affecting, 32 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 32, Intron 11, Nonsense Mutation 4, 5'UTR 4, 3'Flank 3, Frame Shift Del 1, 3'UTR 1, Splice Site 1, RNA 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4135G>T p.E1379* | Nonsense Mutation (SNP) | VAF 177/505 reads (35%) | hotspot (GDC flag); catalogued as rs121913326, COSV57320699, COSV57391553; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3129G>C p.M1043I | Missense Mutation (SNP) | VAF 33/248 reads (13%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as CM126698, COSV55873376, COSV55878974, COSV55898229; called by muse, mutect2, varscan2
- ABTB1 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 40/207 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as rs143409626; called by muse, mutect2, varscan2
- AEN | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 61/582 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs747362453; called by muse, mutect2
- AGPAT4 | c.461C>T p.T154M | Missense Mutation (SNP) | VAF 169/665 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.78); catalogued as rs781252538, COSV57248906; called by muse, mutect2, varscan2
- ANK2 | c.478A>G p.T160A | Missense Mutation (SNP) | VAF 44/324 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764808318; called by muse, mutect2, varscan2
- ATP2B2 | c.1594G>A p.A532T (on ENST00000352432; = p.A498T on NM_001683.5) | Missense Mutation (SNP) | VAF 66/335 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.572); catalogued as rs777396418, COSV59489637; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C11orf87 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 61/428 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100535913; called by muse, mutect2, varscan2
- CCDC116 | c.1427C>T p.S476F | Missense Mutation (SNP) | VAF 57/415 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1314575946, COSV99489540; called by muse, mutect2, varscan2
- CCDC87 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 60/192 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs767088192; called by muse, mutect2, varscan2
- CDH4 | c.886G>A p.V296M | Missense Mutation (SNP) | VAF 75/153 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs770909673, COSV64661545; called by muse, mutect2, varscan2
- CDH4 | c.2551C>T p.R851C | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756374774, COSV100849794; called by muse, mutect2, varscan2
- CFAP47 | c.4483G>A p.E1495K | Missense Mutation (SNP) | VAF 16/290 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0.397); catalogued as COSV57975402; called by muse, mutect2
- CMTM5 | c.319G>T p.D107Y | Missense Mutation (SNP) | VAF 69/374 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV100198056; called by muse, mutect2, varscan2
- COL4A1 | c.2902C>T p.R968* | Nonsense Mutation (SNP) | VAF 32/763 reads (4%) | catalogued as COSV65424009; called by muse, mutect2
- CRHR1 | c.142G>A p.V48M | Missense Mutation (SNP) | VAF 85/270 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.767); catalogued as rs779673418, COSV53277675, COSV53279223; called by muse, mutect2, varscan2
- CYP11A1 | c.919G>A p.G307R | Missense Mutation (SNP) | VAF 189/554 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.019); catalogued as COSV51435155; called by muse, mutect2, varscan2
- DMD | c.2702G>T p.G901V | Missense Mutation (SNP) | VAF 148/663 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.34); catalogued as COSV63735623; called by muse, mutect2, varscan2
- ESR2 | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs200264592, COSV50835079; called by muse, mutect2, varscan2
- F8 | c.6326G>A p.R2109H | Missense Mutation (SNP) | VAF 166/618 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs781947839, CD108738; called by muse, mutect2, varscan2
- FAM90A1 | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 112/1507 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1435488412; called by muse, mutect2
- FTMT | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs572583166; called by muse, mutect2, varscan2
- GLDC | c.2591T>C p.I864T | Missense Mutation (SNP) | VAF 38/227 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV58676348; called by muse, mutect2, varscan2
- GRIK3 | c.1744G>A p.V582I | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.844); catalogued as rs371012951, COSV66136375, COSV66144296; called by muse, mutect2, varscan2
- HCN4 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 109/327 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756293276, COSV56082563; called by muse, mutect2, varscan2
- MN1 | c.1949C>T p.S650L | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.086); catalogued as rs1211157447; called by muse, mutect2, varscan2
- MTBP | c.1292A>G p.N431S | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs200705006; called by muse, mutect2, varscan2
- NAIF1 | c.331G>A p.G111S | Missense Mutation (SNP) | VAF 39/199 reads (20%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs1457940427, COSV66091970; called by muse, mutect2, varscan2
- NLRP5 | c.1366C>T p.R456C | Missense Mutation (SNP) | VAF 48/305 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.071); catalogued as rs780213439, COSV66764769; called by muse, mutect2, varscan2
- OR2A14 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 208/547 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.499); catalogued as rs1481069147, COSV68718411; called by muse, mutect2, varscan2
- OR5F1 | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 14/334 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV53545471; called by muse, mutect2
- PCDHB12 | c.1709C>T p.A570V | Missense Mutation (SNP) | VAF 376/1031 reads (36%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.059); catalogued as rs1554286996, COSV53394760; called by muse, mutect2, varscan2
- PEG3 | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.154); catalogued as rs762141634, COSV55631527, COSV55638935; called by muse, mutect2, varscan2
- PELO | c.1099C>T p.R367C | Missense Mutation (SNP) | VAF 80/179 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1438852730; called by muse, mutect2, varscan2
- PKHD1 | c.10522G>A p.V3508I | Missense Mutation (SNP) | VAF 172/629 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as rs752984925, COSV64382790; called by muse, mutect2, varscan2
- PLXNA1 | c.1327C>T p.R443W | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as rs576258194, COSV99303138; called by muse, mutect2, varscan2
- PRR23A | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 45/268 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.124); catalogued as rs774632155, COSV67213819; called by muse, mutect2, varscan2
- PYGM | c.1919G>A p.R640H | Missense Mutation (SNP) | VAF 124/720 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs141267088; called by muse, mutect2, varscan2
- SLC13A4 | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as COSV62460048; called by muse, mutect2, varscan2
- SOWAHA | c.1150G>A p.G384S | Missense Mutation (SNP) | VAF 31/188 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1388661951; called by muse, mutect2, varscan2
- SPNS3 | c.1303C>T p.R435C | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.872); catalogued as rs747755316, COSV61069271; called by muse, mutect2, varscan2
- SUSD2 | c.2141G>A p.R714H | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1236490592; called by muse, mutect2
- TP53 | c.672G>T p.E224D | Missense Mutation (SNP) | VAF 138/393 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as rs267605076, CS100446, COSV52678333, COSV52681634, COSV52721244; called by mutect2, varscan2
- TTN | c.29990T>C p.I9997T (on ENST00000591111; = p.I9070T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/350 reads (10%) | PolyPhen benign (0.127); catalogued as rs886055288; ClinVar: uncertain significance; called by muse, mutect2
- ZNF667 | c.1780C>T p.R594W | Missense Mutation (SNP) | VAF 34/206 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as rs777166123, COSV52633055; called by muse, mutect2, varscan2
- ZNF75A | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs370943522; called by muse, mutect2, varscan2
- ZNRF3 | c.2632C>T p.R878W (on ENST00000544604 / NM_001206998.2; = p.R778W on NM_032173.3) | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs201527056; called by muse, mutect2, varscan2
- ZSCAN1 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 89/245 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.036); catalogued as rs373056173; called by muse, mutect2, varscan2
- ADAM33 | c.1274T>C p.V425A | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- CACNB4 | c.767T>C p.I256T | Missense Mutation (SNP) | VAF 51/310 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CROCC | c.2446G>T p.E816* | Nonsense Mutation (SNP) | VAF 72/507 reads (14%) | called by muse, mutect2, varscan2
- CYP26B1 | c.450_456del p.S150Rfs*13 | Frame Shift Del (DEL) | VAF 178/596 reads (30%) | called by mutect2, pindel, varscan2
- CYSLTR1 | c.504_505insC p.N169Qfs*2 | Frame Shift Ins (INS) | VAF 34/353 reads (10%) | called by mutect2, pindel
- DOCK10 | c.2182G>A p.A728T | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KDM1A | c.2500T>C p.Y834H | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- KLF5 | c.920C>T p.S307L | Missense Mutation (SNP) | VAF 60/401 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LAMA3 | c.940G>C p.E314Q | Missense Mutation (SNP) | VAF 46/354 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.438); called by mutect2, varscan2
- LIMD1 | c.608G>C p.S203T | Missense Mutation (SNP) | VAF 68/339 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NCOA5 | c.1016C>T p.P339L | Missense Mutation (SNP) | VAF 53/638 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PACS2 | c.1300C>T p.R434W | Missense Mutation (SNP) | VAF 62/119 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCSK7 | c.622G>C p.D208H | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PIK3C2B | c.2254A>G p.K752E | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.813); called by muse, mutect2
- PIK3CD | c.2458G>A p.D820N | Missense Mutation (SNP) | VAF 114/381 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- PRR23B | c.88C>T p.R30* | Nonsense Mutation (SNP) | VAF 22/133 reads (17%) | called by muse, mutect2, varscan2
- RBBP9 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- RGS14 | c.267C>G p.F89L | Missense Mutation (SNP) | VAF 57/134 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- RPGR | c.2397G>T p.E799D (on ENST00000339363 / NM_001367249.1; = p.E594D on NM_000328.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 160/478 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.76); called by mutect2, varscan2
- SERPINA9 | c.1084G>C p.E362Q | Missense Mutation (SNP) | VAF 14/296 reads (5%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.752); called by muse, mutect2
- SLC6A18 | c.1864C>T p.R622C | Missense Mutation (SNP) | VAF 90/337 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- SORCS2 | c.2327C>A p.P776H | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTN | c.30788A>T p.K10263M (on ENST00000591111; = p.K9336M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/218 reads (17%) | PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- UQCRB | c.19+1G>A p.X7_splice | Splice Site (SNP) | VAF 121/370 reads (33%) | called by muse, mutect2, varscan2
- VILL | c.991G>C p.V331L | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- ZFPM2 | c.2147C>G p.P716R | Missense Mutation (SNP) | VAF 170/673 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF292 | c.6709C>G p.L2237V | Missense Mutation (SNP) | VAF 38/309 reads (12%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ADAM21 | c.1191T>G p.P397= | Silent (SNP) | VAF 208/623 reads (33%) | called by muse, mutect2, varscan2
- AQP8 | c.744C>T p.F248= | Silent (SNP) | VAF 25/206 reads (12%) | called by muse, mutect2, varscan2
- CC2D1A | c.1704G>C p.L568= | Silent (SNP) | VAF 32/128 reads (25%) | called by mutect2, varscan2
- CCDC168 | c.5478A>G p.V1826= | Silent (SNP) | VAF 48/375 reads (13%) | catalogued as COSV70554913; called by muse, mutect2, varscan2
- CCDC183 | c.1524C>T p.V508= | Silent (SNP) | VAF 21/106 reads (20%) | called by muse, mutect2, varscan2
- COL3A1 | c.186C>T p.C62= | Silent (SNP) | VAF 74/475 reads (16%) | catalogued as rs764749176, COSV58593556; ClinVar: likely benign; called by muse, mutect2, varscan2
- CSMD2 | c.1872C>T p.D624= | Silent (SNP) | VAF 147/420 reads (35%) | catalogued as rs755606815, COSV53886380, COSV53926138; called by muse, mutect2, varscan2
- CTNND2 | c.1506C>A p.P502= | Silent (SNP) | VAF 33/115 reads (29%) | called by muse, mutect2, varscan2
- DCSTAMP | c.855G>A p.P285= | Silent (SNP) | VAF 29/277 reads (10%) | catalogued as rs553927963, COSV52579386; called by muse, mutect2, varscan2
- DOCK3 | c.4224C>T p.D1408= | Silent (SNP) | VAF 35/213 reads (16%) | catalogued as rs371805365; called by muse, mutect2, varscan2
- DRD5 | c.75C>T p.N25= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as COSV100431859; called by muse, mutect2, varscan2
- DSCAML1 | c.4248G>A p.E1416= (on ENST00000321322; = p.E1356= on NM_020693.4) | Silent (SNP) | VAF 34/216 reads (16%) | called by muse, mutect2, varscan2
- FAM71E1 | c.543G>C p.L181= (on ENST00000600100 / NM_001308429.2; = p.L165= on NM_138411.3) | Silent (SNP) | VAF 109/364 reads (30%) | called by mutect2, varscan2
- HPCAL1 | c.231C>T p.D77= | Silent (SNP) | VAF 50/405 reads (12%) | catalogued as rs1324636807, COSV57144782; called by muse, mutect2, varscan2
- HYDIN | c.11649C>T p.A3883= | Silent (SNP) | VAF 68/318 reads (21%) | catalogued as rs547639554; called by muse, mutect2, varscan2
- IGHA1 | c.450C>T p.T150= | Silent (SNP) | VAF 148/377 reads (39%) | catalogued as rs397832538; called by muse, mutect2, varscan2
- IRX1 | c.360C>T p.Y120= | Silent (SNP) | VAF 138/461 reads (30%) | catalogued as COSV57358565; called by muse, mutect2, varscan2
- LRRC8E | c.1044G>A p.R348= | Silent (SNP) | VAF 63/385 reads (16%) | called by muse, mutect2, varscan2
- MARCHF8 | c.870C>T p.H290= | Silent (SNP) | VAF 66/192 reads (34%) | catalogued as rs370727534, COSV60572752; called by muse, mutect2, varscan2
- NLRP5 | c.912G>A p.A304= | Silent (SNP) | VAF 47/282 reads (17%) | catalogued as rs368367207, COSV101173770; called by muse, mutect2, varscan2
- OR9Q1 | c.786C>T p.N262= | Silent (SNP) | VAF 48/364 reads (13%) | called by muse, mutect2, varscan2
- PDE1C | c.810C>T p.Y270= | Silent (SNP) | VAF 33/165 reads (20%) | catalogued as rs375192379, COSV100370815; called by muse, mutect2, varscan2
- PKD1L1 | c.5397G>A p.A1799= | Silent (SNP) | VAF 24/212 reads (11%) | catalogued as rs548476706, COSV99220018; called by muse, mutect2, varscan2
- PRDM12 | c.291C>T p.G97= | Silent (SNP) | VAF 25/155 reads (16%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.946C>A p.R316= (on ENST00000265814 / NM_001198628.1; = p.R289= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 60/201 reads (30%) | catalogued as COSV56139154; called by muse, mutect2, varscan2
- SRRM2 | c.6207A>G p.T2069= | Silent (SNP) | VAF 129/446 reads (29%) | catalogued as rs766626495; called by muse, mutect2, varscan2
- SYNE1 | c.24162G>A p.T8054= (on ENST00000367255 / NM_182961.4; = p.T7983= on NM_033071.3) | Silent (SNP) | VAF 91/623 reads (15%) | catalogued as rs185088779; ClinVar: likely benign / uncertain significance / benign; called by muse, mutect2, varscan2
- TRPM1 | c.1872C>G p.R624= | Silent (SNP) | VAF 146/501 reads (29%) | called by muse, mutect2, varscan2
- UBE4B | c.759A>T p.T253= | Silent (SNP) | VAF 136/366 reads (37%) | called by muse, mutect2, varscan2
- UROC1 | c.1047G>A p.P349= | Silent (SNP) | VAF 99/492 reads (20%) | catalogued as rs373726993; called by muse, mutect2, varscan2
- USP14 | c.750G>A p.E250= | Silent (SNP) | VAF 28/81 reads (35%) | called by muse, mutect2, varscan2
- WIZ | c.1350C>T p.S450= | Silent (SNP) | VAF 15/125 reads (12%) | catalogued as rs1052215091, COSV54609377; called by muse, mutect2, varscan2
- ABCG4 | c.1167+72G>C | Intron (SNP) | VAF 19/340 reads (6%) | called by muse, mutect2
- ACOT7 | c.860-1491C>T | Intron (SNP) | VAF 114/258 reads (44%) | catalogued as rs769566232; called by muse, mutect2, varscan2
- AGPAT4 | c.348+4828G>A | Intron (SNP) | VAF 56/590 reads (9%) | catalogued as rs749457238; called by muse, mutect2
- AP000356.3 | chr22:24645639 G>A | 5'Flank (SNP) | VAF 58/680 reads (9%) | catalogued as rs776028195; called by muse, mutect2
- C10orf53 | c.-15G>A | 5'UTR (SNP) | VAF 34/217 reads (16%) | called by muse, mutect2, varscan2
- CBX2 | c.288+365C>T | Intron (SNP) | VAF 29/280 reads (10%) | catalogued as rs189040749; called by muse, mutect2, varscan2
- DPM3 | c.-31-96G>A | Intron (SNP) | VAF 16/240 reads (7%) | called by muse, mutect2
- ERGIC3 | chr20:35559541 C>G | 3'Flank (SNP) | VAF 232/505 reads (46%) | called by muse, mutect2, varscan2
- ESPN | chr1:6457371 C>T | 3'Flank (SNP) | VAF 151/384 reads (39%) | catalogued as rs746244406, COSV61069367; called by muse, mutect2, varscan2
- GAP43 | c.31-12208C>T | Intron (SNP) | VAF 21/123 reads (17%) | called by muse, mutect2, varscan2
- INPP5F | c.1887-1351C>T | Intron (SNP) | VAF 16/146 reads (11%) | called by muse, mutect2, varscan2
- KLRC2 | c.585-25G>A | Intron (SNP) | VAF 165/544 reads (30%) | called by muse, mutect2, varscan2
- LEUTX | c.-100C>G | 5'UTR (SNP) | VAF 10/146 reads (7%) | called by muse, mutect2
- PIDD1 | c.296-43G>A | Intron (SNP) | VAF 27/128 reads (21%) | catalogued as rs761782167; called by muse, mutect2, varscan2
- POLR3G | c.*119C>T | 3'UTR (SNP) | VAF 31/76 reads (41%) | catalogued as rs772828065; called by muse, mutect2, varscan2
- RIOK2 | c.1494+18A>G | Intron (SNP) | VAF 16/52 reads (31%) | catalogued as rs907769954; called by muse, mutect2, varscan2
- SNORD116-9 | n.79C>T | RNA (SNP) | VAF 29/207 reads (14%) | catalogued as rs764210515; called by muse, mutect2, varscan2
- SULT1A3 | chr16:30206218 G>T | 3'Flank (SNP) | VAF 75/557 reads (13%) | called by muse, mutect2, varscan2
- SYN1 | c.-49C>T | 5'UTR (SNP) | VAF 52/196 reads (27%) | catalogued as rs968471465; called by muse, mutect2, varscan2
- TEX15 | c.-3G>A | 5'UTR (SNP) | VAF 20/119 reads (17%) | catalogued as rs1480144921; called by muse, mutect2, varscan2
- TSPAN7 | c.81+1465C>T | Intron (SNP) | VAF 106/256 reads (41%) | catalogued as rs1332459016; called by muse, mutect2, varscan2
